Somatic mutation profile of tumor specimen TARGET-30-PAMUTD-01A (aliquot TARGET-30-PAMUTD-01A-01W) from TARGET case TARGET-30-PAMUTD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.3 years (825 days).
Specimen TARGET-30-PAMUTD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65da8881-91a6-42e4-9c47-ce72a762d5ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMUTD-10A (Blood Derived Normal), aliquot TARGET-30-PAMUTD-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5e4a749-35a0-44e9-a156-d965f587724c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1S | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV61071843; called by muse, mutect2, varscan2
- GABRA6 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772232018, COSV50888036; called by muse, mutect2, varscan2
- MTUS2 | c.3044C>A p.A1015E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV70919028; called by muse, mutect2, varscan2
- SCN8A | c.5065G>T p.E1689* | Nonsense Mutation (SNP) | VAF 65/218 reads (30%) | catalogued as rs1555230962, COSV61988247; called by muse, mutect2, varscan2
- TLR6 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67935465, COSV67935565; called by muse, mutect2, varscan2
- TRIM31 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 143/399 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV65059930, COSV65060047; called by muse, mutect2, varscan2
- ZFHX4 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51479901; called by muse, mutect2, varscan2
- FBLN2 | c.3291_3300dup p.A1101Pfs*29 | Frame Shift Ins (INS) | VAF 15/78 reads (19%) | called by mutect2, varscan2
- ESR1 | c.1653G>A p.A551= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs200930301, COSV52797667; called by muse, mutect2, varscan2
- MDN1 | c.8193C>A p.A2731= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV65526660; called by muse, mutect2, varscan2
- OSBPL3 | c.570G>A p.Q190= | Silent (SNP) | VAF 84/227 reads (37%) | catalogued as COSV57656320, COSV57660228; called by muse, mutect2, varscan2
